Somatic mutation profile of tumor specimen C3N-00314-02 (aliquot CPT0012060012) from CPTAC case C3N-00314, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.0 years (28,865 days).
Specimen C3N-00314-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 788108c5-9560-4883-9df1-d71ea1439c25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00314-31 (Blood Derived Normal), aliquot CPT0012150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76691b52-1a8e-48ef-83cc-0e45f31c1a32

The open-access MAF lists 125 somatic variants for this specimen: 86 protein-altering or splice-affecting, 26 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 26, Frame Shift Del 11, Intron 9, Splice Region 4, Nonsense Mutation 3, In Frame Del 2, 3'Flank 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3712G>A p.G1238S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs200733032; called by muse, mutect2, varscan2
- AKAP13 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs779331144, COSV63466066; called by muse, mutect2, varscan2
- AP3B1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV54877011; called by muse, mutect2, varscan2
- APMAP | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs145483793, COSV54176004; called by muse, mutect2
- CACNA1C | c.3912+1G>A p.X1304_splice | Splice Site (SNP) | VAF 21/84 reads (25%) | catalogued as rs1247088024; called by muse, mutect2, varscan2
- CALML6 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV57069100; called by muse, mutect2
- CARD10 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.194); catalogued as rs769750011, COSV99325255; called by muse, mutect2
- CFAP20DC | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.296); catalogued as rs986587169; called by muse, mutect2, varscan2
- CSMD3 | c.4069C>G p.P1357A (on ENST00000297405 / NM_001363185.1; = p.P1253A on NM_052900.3) | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52108152; called by muse, mutect2, varscan2
- DDI1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114046986; called by muse, mutect2, varscan2
- DISP1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as rs908032421, COSV99450110; called by muse, mutect2, varscan2
- DNAH5 | c.13084G>T p.D4362Y | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54234974; called by muse, mutect2, varscan2
- HIVEP2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775033088, COSV50012224; called by muse, mutect2
- LILRA4 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52494279; called by muse, mutect2
- LRWD1 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 37/631 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs769022777, COSV99479556; called by muse, mutect2
- MALRD1 | c.5439G>T p.W1813C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV65978183; called by muse, mutect2, varscan2
- MMS22L | c.2164_2168del p.F722Ifs*54 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | catalogued as rs762465123; called by mutect2, pindel
- PDCL3 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748802211; called by muse, mutect2, varscan2
- RRP12 | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781493704; called by mutect2, varscan2
- SYNJ2 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745840620; called by muse, mutect2, varscan2
- TMEM163 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323094328; called by muse, mutect2, varscan2
- ZNF207 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 42/265 reads (16%) | catalogued as COSV58301642; called by muse, mutect2, varscan2
- ZNF419 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1397210318; called by muse, mutect2
- ZNF853 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1197370268; called by muse, mutect2
- ABCC5 | c.1832A>G p.Q611R | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ABCC8 | c.1288T>A p.W430R | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- AC004593.2 | c.608C>G p.T203R | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACBD5 | c.794A>C p.E265A (on ENST00000375888 / NM_001352568.1; = p.E256A on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- AKAP11 | c.2480A>T p.E827V | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- AKAP12 | c.4543G>A p.V1515I | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- AKIRIN2 | c.204del p.F69Sfs*17 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.3771dup p.L1258Tfs*4 | Frame Shift Ins (INS) | VAF 19/158 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.7713+3A>T | Splice Region (SNP) | VAF 14/394 reads (4%) | called by muse, mutect2
- ANKRD42 | c.1058C>G p.T353S | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP32 | c.4746_4747del p.R1582Sfs*26 (on ENST00000310343 / NM_001378025.1; = p.R1233Sfs*26 on NM_014715.4) | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | called by pindel, varscan2
- ARNT2 | c.2137C>G p.P713A | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- BMP5 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC178 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CCDC9 | c.246del p.T83Pfs*85 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- CEACAM1 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHAT | c.1980G>T p.V660= | Splice Region (SNP) | VAF 33/240 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.698_700del p.G233del | In Frame Del (DEL) | VAF 28/234 reads (12%) | called by mutect2, pindel, varscan2
- COL6A5 | c.4669G>T p.E1557* | Nonsense Mutation (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2, varscan2
- CRIM1 | c.2788C>T p.H930Y | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- DNMT1 | c.79C>A p.R27= | Splice Region (SNP) | VAF 34/234 reads (15%) | called by muse, mutect2, varscan2
- DPPA2 | c.329G>C p.S110T | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DUXB | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ESPL1 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FAM199X | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- FN1 | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FOS | c.897T>G p.Y299* | Nonsense Mutation (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- FOXN1 | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2
- GASK1B | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GEMIN5 | c.417del p.F139Lfs*11 | Frame Shift Del (DEL) | VAF 36/194 reads (19%) | called by mutect2, pindel, varscan2
- HRNR | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 81/565 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGSF10 | c.6162del p.D2055Ifs*4 | Frame Shift Del (DEL) | VAF 35/190 reads (18%) | called by mutect2, pindel, varscan2
- ITIH6 | c.3354del p.L1119Cfs*3 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- KCNG1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KIAA0895L | c.1326G>C p.Q442H | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, mutect2
- KLRG2 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARP4B | c.1610del p.L537Yfs*8 | Frame Shift Del (DEL) | VAF 30/193 reads (16%) | called by mutect2, pindel, varscan2
- LIF | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MECOM | c.1426G>T p.A476S (on ENST00000468789 / NM_001105078.4; = p.A664S on NM_004991.4) | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MOSPD3 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MUC16 | c.4522G>T p.A1508S | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); called by muse, mutect2
- NUTM1 | c.1600del p.R534Efs*11 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- OTUD7A | c.1706A>T p.E569V (on ENST00000307050 / NM_001382637.1; = p.E562V on NM_130901.3) | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- PBRM1 | c.2818del p.L940Sfs*74 (on ENST00000296302 / NM_001366071.2; = p.L940Sfs*68 on NM_018313.5) | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- PCNT | c.8040G>T p.E2680D | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIKFYVE | c.5074C>A p.Q1692K | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RCC1 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.955); called by muse, mutect2
- RGMB | c.4G>T p.G2C (on ENST00000513185 / NM_001366508.1; = p.G43C on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); called by muse, varscan2
- SAFB2 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCO1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SDAD1 | c.196-5T>A | Splice Region (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- SLC35D2 | c.935_940del p.Y312_S313del | In Frame Del (DEL) | VAF 18/147 reads (12%) | called by mutect2, pindel, varscan2
- SLTM | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG1 | c.7465G>A p.D2489N | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SNX25 | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, varscan2
- TOE1 | c.295T>A p.S99T | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TP53BP2 | c.2746A>G p.K916E (on ENST00000343537 / NM_001031685.3; = p.K787E on NM_005426.2) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TSPY1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 122/1484 reads (8%) | called by muse, mutect2
- ZBTB16 | c.1037T>G p.L346W | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZCCHC7 | c.556_563del p.K186* | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | called by muse*, mutect2
- ZMYM4 | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF512B | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AK3 | c.457C>T p.L153= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- BPIFB3 | c.840G>A p.V280= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- CAPN1 | c.315A>T p.T105= | Silent (SNP) | VAF 30/164 reads (18%) | called by muse, mutect2, varscan2
- CDH18 | c.1833G>A p.L611= | Silent (SNP) | VAF 13/258 reads (5%) | catalogued as rs1381407091; called by muse, mutect2
- DOK2 | c.1116G>T p.A372= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, varscan2
- ESYT3 | c.309C>T p.G103= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- EXT2 | c.657G>A p.T219= (on ENST00000343631; = p.T252= on NM_000401.3) | Silent (SNP) | VAF 38/494 reads (8%) | catalogued as rs368087959, COSV59155038; called by muse, mutect2
- HIP1 | c.309C>G p.L103= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.231T>C p.H77= | Silent (SNP) | VAF 33/204 reads (16%) | catalogued as rs1170472411, COSV51533984; called by muse, mutect2, varscan2
- KCNG1 | c.1182G>C p.L394= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV65369535; called by muse, mutect2, varscan2
- KMT2C | c.8979C>T p.L2993= | Silent (SNP) | VAF 34/270 reads (13%) | catalogued as COSV51439610; called by muse, mutect2, varscan2
- MYH11 | c.27C>T p.D9= | Silent (SNP) | VAF 10/249 reads (4%) | catalogued as rs769179119; ClinVar: likely benign; called by muse, mutect2
- NEUROD2 | c.1071T>C p.N357= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- NVL | c.234A>G p.L78= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- PHF3 | c.1857A>T p.V619= | Silent (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- PLXNA4 | c.4473C>T p.I1491= | Silent (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- PRSS27 | c.444C>T p.P148= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs915952005; called by muse, mutect2, varscan2
- PTX4 | c.501G>A p.R167= (on ENST00000447419 / NM_001328608.2; = p.R162= on NM_001013658.1) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99560379; called by muse, mutect2
- SERPINB6 | c.1179C>G p.S393= (on ENST00000612421 / NM_001271823.2; = p.S374= on NM_004568.6) | Silent (SNP) | VAF 38/232 reads (16%) | catalogued as rs768602128; called by muse, mutect2, varscan2
- SH3GLB1 | c.1053C>T p.N351= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- TMEM151B | c.882C>A p.P294= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- TMEM236 | c.948A>T p.T316= | Silent (SNP) | VAF 84/572 reads (15%) | called by mutect2, varscan2
- TMEM265 | c.30C>A p.I10= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- ZFR2 | c.1173G>A p.A391= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs963844831, COSV53596101; called by muse, mutect2
- ZMYND8 | c.2904G>A p.E968= (on ENST00000311275 / NM_001363741.2; = p.E942= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV53696825; called by muse, mutect2, varscan2
- ZNF516 | c.12C>T p.N4= | Silent (SNP) | VAF 26/203 reads (13%) | catalogued as rs754764602; called by muse, mutect2, varscan2
- AC116366.2 | c.-659_-655del | 5'UTR (DEL) | VAF 37/203 reads (18%) | called by mutect2, pindel, varscan2
- ALOXE3 | chr17:8118767 C>T | 5'Flank (SNP) | VAF 22/206 reads (11%) | catalogued as rs1298426740; called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39434C>T | Intron (SNP) | VAF 60/361 reads (17%) | called by muse, mutect2, varscan2
- CACNB4 | c.390+55T>G | Intron (SNP) | VAF 38/198 reads (19%) | called by muse, mutect2, varscan2
- HBD | c.-29+258A>T | Intron (SNP) | VAF 9/239 reads (4%) | called by muse, mutect2
- NME5 | c.129+27dup | Intron (INS) | VAF 20/134 reads (15%) | called by mutect2, varscan2
- PHF20 | c.1826-137del | Intron (DEL) | VAF 30/219 reads (14%) | called by mutect2, pindel, varscan2
- RMDN1 | chr8:86468706 del C | 3'Flank (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
- RN7SL484P | chr15:99792697 G>A | 3'Flank (SNP) | VAF 24/182 reads (13%) | catalogued as rs1407716729; called by muse, mutect2, varscan2
- SLC27A4 | c.-6-857C>T | Intron (SNP) | VAF 20/230 reads (9%) | catalogued as rs551080094, COSV55960798, COSV55960909; called by muse, mutect2
- ZNF398 | c.25-2686C>T | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- ZNF528 | c.272-836C>G | Intron (SNP) | VAF 21/217 reads (10%) | catalogued as rs761426106; called by muse, mutect2, varscan2
- ZNF829 | c.-85+146A>C | Intron (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
